TCGA case TCGA-19-0955 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Case Western. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f473a0d0-72b6-465e-93f7-122224960e80

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 71.1 years (25,974 days); Year of diagnosis: 2007; Method of diagnosis: Fine Needle Aspiration; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 31 days; Days to treatment end: 70 days; Treatment dose: 460 cGy; Number of fractions: 23; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 31 days; Days to treatment end: 277 days; Number of cycles: 6; Treatment dose: 360 mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 79 days; Days to treatment end: 79 days; Treatment dose: 140 cGy; Number of fractions: 7; Treatment anatomic sites: Primary Tumor Field.

Follow-up (1 entry)
- Days to follow up: 358 days; Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-19-0955-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.8; Intermediate dimension: 1; Shortest dimension: 0.8.
  Slide TCGA-19-0955-01A-02-BS2: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
  Slide TCGA-19-0955-01A-01-BS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-19-0955-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-19-0955-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: Tumor free; History neoadjuvant treatment: No; Method initial path diagnosis: Fine needle aspiration biopsy.
- Drug treatment, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 358 days; disease-specific survival: no event (censored), 358 days; progression-free interval: no event (censored), 358 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-19-0955-01): tumor purity 0.52, ploidy 2.11, whole-genome doublings 0 (call status: legacy_call).
